Gene-level copy-number profile of tumor specimen TCGA-29-1710-01A from TCGA case TCGA-29-1710, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 54.7 years (19,969 days).
Specimen TCGA-29-1710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.39807bf8-d0a9-4817-9094-2577dd21157b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1710-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d45596c7-703e-47c9-9755-063799280d0c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,002; copy number 2: 15,800; copy number 3: 31,598; copy number 4: 4,608; copy number 5: 4,784; copy number 6: 453; copy number 7: 342; copy number 8: 139; copy number 9: 31; copy number 10: 12; copy number 13: 8; copy number 17: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1710-01A-02D-0559-01): tumor purity 0.47, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 569 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:108,032,456–117,139,389, 139 genes, copy number 8 (within-gene range 1–8) (broad region; genes not listed).
- chr3:117,544,205–117,997,592, 5 genes, copy number 7: RNU6-1200P, AC092691.1, AC092691.2, LINC02024, AC092691.3.
- chr3:182,588,093–187,805,258, 151 genes, copy number 7 (broad region; genes not listed).
- chr6:28,732,017–29,431,967, 37 genes, copy number 7 (within-gene range 4–7): RPSAP2, NOP56P1, AL662890.1, LINC01623, RPL13P, ZNF90P2, HCG14, TRIM27, RNU6-930P, LINC01556, KRT18P1, RN7SL471P, HCG15, AL662791.1, ZNF311, OR2AD1P, AL662791.2, OR2W1, OR2P1P, SAR1AP1, OR2B3, OR2J1, OR2J3, AL645937.2, AL645937.1, AL645937.4, OR2J2, OR2J4P, AL645937.3, AL672167.1, OR2G1P, OR2U1P, OR2U2P, OR14J1, DDX6P1, OR5V1, OR12D3.
- chr8:121,639,293–121,994,185, 1 gene, copy number 7 (within-gene range 3–7): HAS2-AS1.
- chr8:121,954,640–125,091,819, 77 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr19:18,957,957–20,321,305, 71 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr19:27,793,431–27,984,984, 1 gene, copy number 13 (within-gene range 4–13): AC006504.5.
- chr19:27,849,635–30,957,192, 61 genes, copy number 9–17 (within-gene range 4–17) (broad region; genes not listed).
- chr19:55,769,118–56,185,775, 14 genes, copy number 9 (within-gene range 5–9): RFPL4AL1, RFPL4AP1, NLRP11, NLRP4, NLRP13, NLRP8, NLRP5, LINC01864, ZNF787, Y_RNA, AC024580.2, ZNF444, AC024580.1, GALP.
- chr19:56,439,325–56,626,481, 12 genes, copy number 10 (within-gene range 2–10): ZNF667, ZNF667-AS1, AC004696.2, AC004696.1, ZNF471, AC005498.1, AC005498.2, ZFP28, AC005498.3, ZNF470, SIGLEC31P, ZNF71.

Autosomal genes at a single copy (total copy number 1): 1,091. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
